Somatic mutation profile of tumor specimen TCGA-EJ-AB27-01A (aliquot TCGA-EJ-AB27-01A-11D-A41K-08) from TCGA case TCGA-EJ-AB27, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.1 years (18,648 days).
Specimen TCGA-EJ-AB27-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52fa5036-1f66-40ed-b435-734a8192158e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-AB27-10A (Blood Derived Normal), aliquot TCGA-EJ-AB27-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f803a4-0b5e-466e-b63f-68019feac897

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA2 | c.558A>T p.E186D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99570122; called by muse, mutect2
- CEP41 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | catalogued as rs782286004, COSV99782744; ClinVar: uncertain significance; called by muse, mutect2
- COL5A1 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1330022009, COSV65675309; ClinVar: uncertain significance; called by muse, mutect2
- CUBN | c.10693G>A p.V3565I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV100912890; called by muse, mutect2
- FILIP1L | c.890C>T p.T297M (on ENST00000354552 / NM_182909.3; = p.T57M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV100496039; called by muse, mutect2
- MITF | c.496C>T p.H166Y (on ENST00000448226 / NM_006722.3; = p.H60Y on NM_000248.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1383949502, COSV100097021; called by muse, mutect2, varscan2
- PKD1L1 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.417); catalogued as rs566918758, COSV99220121; called by mutect2, varscan2
- PLB1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV100578955; called by muse, mutect2, varscan2
- RNF138 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as rs1309524763, COSV99857532; called by muse, mutect2
- SYNRG | c.2681A>G p.Y894C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1438279174; called by muse, mutect2
- TMEM30A | c.102A>C p.K34N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100034935; called by muse, mutect2, varscan2
- UBA6 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451744; called by muse, mutect2
- ATP13A1 | c.1521C>T p.A507= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99366267; called by mutect2, varscan2
- DGKE | c.1695G>A p.A565= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs775303853, COSV52351383; called by mutect2, varscan2
- EMD | c.711C>T p.I237= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs727503037, COSV100877380; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPA12A | c.234G>A p.P78= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs199810572; called by muse, mutect2
- PCDHB6 | c.2124G>A p.A708= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as rs375622168, COSV50689541; called by muse, mutect2
